Surgical pathology report (de-identified scan), TCGA case TCGA-F9-A7Q0, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site Asterand, specimen TCGA-F9-A7Q0-01A (Primary Tumor).

Patient ID:

Surgical Date:

Gross Description: Renal tumor is located in a pole, moderately-margin, soft, solid, or yellow, gray surface with 5x4x4cm in size.

Microscopic Description: Tumor is high density and is composed of elongated tubules or papillary, back to back, variability in shape and size, lined by moderately stratified cylindrical or cuboidal cells. Nuclei are irregular large, hyperchromatic with prominent nucleoli. Mitoses are present. Cytoplasm are moderate, eosinophilic or clear.

Diagnosis Details: Renal cell carcinoma, papillary type

Comments:

Formatted Path Reports: KIDNEY TISSUE CHECKLIST

Specimen type: Radical nephrectomy

Tumor site: Kidney

Tumor size: 5 x 4 x 4 cm

Focality: Single -

Histologic type: Papillary renal cell carcinoma

Histologic grade: Moderately differentiated

Tumor extent: Limited to kidney

Lymph nodes: Not specified

Lymphatic invasion: Not specified

Venous invasion: Not specified

Margins: Not specified

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Not specified

Comments: Left

ICD-O-3
Carcinoma papillary renal cell
8260/3
Site ④ Kidney NOS C64.9
JW 9/26/13

Source: NCI Genomic Data Commons file 374d0c84-e396-421c-9570-8014d1095473 (TCGA-F9-A7Q0.721F9FA7-A956-4B8D-89DC-339AB0CAC3D5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).